Somatic mutation profile of tumor specimen 0DGDWH from CCDI case PBBTFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,753 days).
Specimen 0DGDWH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14111a34-b098-47f4-aee4-54a8050d74c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGDW3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7710e3a-7cdb-4db4-b3c0-bcb1647c589c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 3, Splice Site 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 283/591 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 119/406 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1177C>T p.R393* (on ENST00000281708 / NM_001349798.2; = p.R313* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 336/814 reads (41%) | hotspot (GDC flag); catalogued as COSV55892695; called by muse, mutect2, varscan2
- SMARCA4 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 250/578 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100757983, COSV60796547, COSV60801666; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 219/889 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BACH2 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 94/96 reads (98%) | catalogued as rs1332178350; called by muse, mutect2, varscan2
- CDC37 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 164/383 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs149499190; called by muse, mutect2, varscan2
- DLGAP2 | c.1442+1G>A p.X481_splice | Splice Site (SNP) | VAF 212/474 reads (45%) | catalogued as CS157853, COSV70100477; called by muse, mutect2
- MRGPRF | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 25/546 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57996008; called by muse, mutect2
- PIK3C2B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1403962633; called by muse, mutect2, varscan2
- PSME4 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 300/677 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142928312, COSV66366619; called by muse, mutect2, varscan2
- RGL3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 224/461 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1419950017, COSV66507737; called by muse, mutect2, varscan2
- TTN | c.24292G>C p.A8098P (on ENST00000591111; = p.A7171P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/393 reads (53%) | PolyPhen probably damaging (0.946); catalogued as COSV100589283; called by muse, mutect2, varscan2
- ABCA6 | c.1738T>A p.F580I | Missense Mutation (SNP) | VAF 145/795 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CAPN15 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 26/983 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- DDX3X | c.635T>G p.I212S (on ENST00000399959; = p.I213S on NM_001356.5) | Missense Mutation (SNP) | VAF 19/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX3X | c.1145C>T p.A382V (on ENST00000399959; = p.A383V on NM_001356.5) | Missense Mutation (SNP) | VAF 120/361 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH7 | c.1910C>A p.A637D | Missense Mutation (SNP) | VAF 311/749 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.7697C>T p.T2566I | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.8732C>A p.T2911N (on ENST00000379442; = p.T2768N on NM_001164462.1) | Missense Mutation (SNP) | VAF 64/1044 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); called by muse, mutect2
- PRPF19 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 158/413 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TASP1 | c.676-1G>A p.X226_splice | Splice Site (SNP) | VAF 386/820 reads (47%) | called by muse, mutect2, varscan2
- ZNF644 | c.3853C>T p.Q1285* (on ENST00000337393 / NM_201269.3; = p.Q63* on NM_016620.3) | Nonsense Mutation (SNP) | VAF 393/859 reads (46%) | called by muse, mutect2, varscan2
- CNTN1 | c.2106C>T p.D702= | Silent (SNP) | VAF 194/425 reads (46%) | catalogued as rs147943881; called by muse, mutect2, varscan2
- DNAH5 | c.7560G>A p.P2520= | Silent (SNP) | VAF 66/518 reads (13%) | catalogued as rs762130845; called by muse, mutect2, varscan2
- PTGIR | c.51G>A p.P17= | Silent (SNP) | VAF 172/365 reads (47%) | catalogued as rs200949277; called by muse, mutect2, varscan2
- TENT4B | c.1278G>A p.R426= (on ENST00000561678 / NM_001365323.2; = p.R411= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/844 reads (5%) | called by muse, mutect2
- POLR2F | c.*4G>A | 3'UTR (SNP) | VAF 206/440 reads (47%) | catalogued as rs557222469; called by muse, mutect2, varscan2
- TCF12 | c.1189-815C>T | Intron (SNP) | VAF 504/1118 reads (45%) | catalogued as rs371549670; called by muse, mutect2, varscan2
